Gene-level copy-number profile of tumor specimen TCGA-CG-4449-01A from TCGA case TCGA-CG-4449, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 81.3 years (29,705 days).
Specimen TCGA-CG-4449-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9448f696-a10a-4036-8fc7-b2b85318e7fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4449-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/691616aa-fe17-47f6-bc6b-02054cb4d50c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 19,207; copy number 2: 32,419; copy number 3: 6,020; copy number 4: 964; copy number 5: 335; copy number 6: 101; copy number 7: 202; copy number 8: 7; copy number 9: 18; copy number 10: 33; copy number 11: 255; copy number 12: 17; copy number 13: 140; copy number 15: 9; copy number 17: 36; copy number 21: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4449-01A-01D-1155-01): tumor purity 0.61, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:80,147,924–80,247,514, 4 genes: PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,182 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 1 gene, copy number 8 (within-gene range 3–8): CASZ1.
- chr1:10,895,761–11,030,528, 5 genes, copy number 8: HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3.
- chr1:11,029,659–11,030,528, 1 gene, copy number 8: AL109811.2.
- chr1:31,365,253–32,605,941, 55 genes, copy number 5 (within-gene range 1–5): FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1, ADGRB2, MIR4254, AL354919.2, SPOCD1, AL354919.1, AL136115.2, PTP4A2, AL136115.1, AL136115.3, KHDRBS1, AL445248.1, TMEM39B, MIR5585, Metazoa_SRP, KPNA6, AL049795.2, TXLNA, CCDC28B, AL049795.1, IQCC, DCDC2B, TMEM234, EIF3I, MTMR9LP, FAM167B, LCK, Metazoa_SRP, Y_RNA, HDAC1, MARCKSL1, AL109945.1, TSSK3, FAM229A, BSDC1, GAPDHP20, AL356986.1, LRRC37A12P, RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A.
- chr1:59,733,227–60,149,784, 8 genes, copy number 5: MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778.
- chr1:117,493,515–117,628,389, 4 genes, copy number 5: AL157902.2, VPS25P1, AL157902.1, TENT5C.
- chr1:201,978,461–202,592,706, 22 genes, copy number 5–7 (within-gene range 2–7): SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2.
- chr1:206,747,980–207,795,513, 33 genes, copy number 5 (within-gene range 2–5): Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55, AL391597.1, CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4.
- chr1:225,700,264–226,412,135, 29 genes, copy number 6: AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1, PARP1, AL359704.1.
- chr1:233,614,106–233,672,514, 1 gene, copy number 5 (within-gene range 2–5): KCNK1.
- chr1:233,724,454–235,650,754, 65 genes, copy number 5–12 (broad region; genes not listed).
- chr1:235,738,005–235,738,989, 1 gene, copy number 7: LDHAP2.
- chr3:184,710,364–185,052,614, 7 genes, copy number 5 (within-gene range 2–5): MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4, VPS8.
- chr6:43,576,185–43,852,333, 13 genes, copy number 7: POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr6:134,520,163–134,950,115, 8 genes, copy number 5 (within-gene range 4–5): AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1.
- chr8:100,133,351–101,492,499, 49 genes, copy number 5: FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr8:123,319,850–127,742,951, 83 genes, copy number 5–12 (broad region; genes not listed).
- chr8:127,795,962–127,960,695, 4 genes, copy number 5: MIR1204, AC084123.1, TMEM75, MIR1205.
- chr10:121,133,090–121,615,839, 5 genes, copy number 5: RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1.
- chr11:34,335,118–35,020,591, 13 genes, copy number 6: MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343.
- chr11:74,235,801–74,842,413, 23 genes, copy number 7: P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169.
- chr11:74,830,574–74,846,209, 2 genes, copy number 7: AP000560.1, RN7SL239P.
- chr11:111,013,452–111,561,745, 23 genes, copy number 7 (within-gene range 2–7): AP003973.4, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN.
- chr13:43,908,669–44,809,630, 20 genes, copy number 5 (within-gene range 3–5): NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2, TUSC8, TSC22D1, AL138960.2, AL139184.1, TSC22D1-AS1, SMARCE1P5, LINC00407, AL356515.1, LINC00330.
- chr14:65,082,034–65,335,183, 9 genes, copy number 7: AL139022.1, RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708.
- chr14:65,411,170–65,412,690, 1 gene, copy number 7: FUT8-AS1.
- chr14:68,683,411–69,023,308, 13 genes, copy number 6: AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1.
- chr15:66,702,236–66,782,849, 1 gene, copy number 5 (within-gene range 3–5): SMAD6.
- chr15:66,808,404–67,195,169, 8 genes, copy number 5 (within-gene range 3–5): AC110048.1, AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1.
- chr15:89,305,198–90,717,141, 71 genes, copy number 5 (broad region; genes not listed).
- chr17:71,829,870–72,644,490, 12 genes, copy number 6–15 (within-gene range 2–15): AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2.
- chr17:72,663,823–72,839,718, 3 genes, copy number 7: RN7SKP180, AC080037.1, AC011120.1.
- chr18:21,871,446–22,169,878, 7 genes, copy number 6 (within-gene range 2–6): AC103987.2, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1.
- chr19:13,731,760–15,379,798, 90 genes, copy number 11 (broad region; genes not listed).
- chr19:15,871,667–16,472,085, 33 genes, copy number 10 (within-gene range 3–10): CYP4F36P, CYP4F2, AC005336.2, AC005336.3, AC005336.1, CYP4F11, OR10H4, CYP4F9P, LINC00661, AC004790.2, LINC00905, SNX33P1, AC004790.1, OR1AB1P, LINC01855, TPM4, AC008894.3, AC008894.1, RAB8A, AC008894.2, HSH2D, CIB3, FAM32A, AC020911.1, Metazoa_SRP, AC020911.3, AP1M1, AC020911.2, KLF2, AC020917.3, EPS15L1, AC020917.4, AC020917.1.
- chr19:20,167,214–22,215,801, 90 genes, copy number 11–17 (broad region; genes not listed).
- chr19:22,286,441–35,233,003, 281 genes, copy number 6–21 (within-gene range 3–21) (broad region; genes not listed).
- chr22:29,978,950–30,574,665, 34 genes, copy number 6 (within-gene range 2–6): AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1.
- chr22:37,204,237–37,666,932, 18 genes, copy number 9 (within-gene range 3–9): SSTR3, Z82188.1, RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT.
- chr22:38,818,452–39,492,194, 31 genes, copy number 5 (within-gene range 4–5): NPTXR, CBX6, AL022318.5, AL022318.1, APOBEC3A, APOBEC3B, APOBEC3B-AS1, APOBEC3C, AL022318.4, APOBEC3D, APOBEC3F, AL022318.2, APOBEC3G, AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1, MGAT3, MGAT3-AS1.

Autosomal genes at a single copy (total copy number 1): 16,848. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
